Gene-level copy-number profile of tumor specimen TCGA-DX-A1KX-01A from TCGA case TCGA-DX-A1KX, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 67.9 years (24,784 days).
Specimen TCGA-DX-A1KX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.d10089cb-3b30-4e1f-a08d-b6a4b4134d18.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A1KX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5ca35085-97e3-4f2e-801e-7f47d933b946

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 875; copy number 2: 7,386; copy number 3: 17,368; copy number 4: 15,738; copy number 5: 6,821; copy number 6: 4,582; copy number 7: 2,563; copy number 8: 2,539; copy number 9: 458; copy number 10: 369; copy number 11: 109; copy number 12: 526; copy number 13: 180; copy number 15: 20; copy number 16: 74; copy number 18: 36; copy number 20: 4; copy number 21: 35; copy number 22: 24; copy number 24: 14; copy number 25: 3; copy number 26: 5; copy number 28: 1; copy number 30: 13; copy number 39: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A1KX-01A-22D-A24M-01): tumor purity 0.6, ploidy 3.98, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 6,810 genes in 55 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,103,583–142,131,016, 12 genes, copy number 8 (within-gene range 5–8): LINC01853, MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr3:9,349,689–9,894,349, 19 genes, copy number 11 (within-gene range 1–11): THUMPD3-AS1, THUMPD3, SETD5, LHFPL4, DUSP5P2, MTMR14, AC022382.2, CPNE9, BRPF1, OGG1, CAMK1, TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC, JAGN1.
- chr4:90,127,535–93,810,157, 20 genes, copy number 7 (within-gene range 5–7): CCSER1, RN7SKP248, AC093729.1, TMSB4XP8, AC004054.1, AC074124.1, AC110774.1, KRT19P6, AC093810.1, PMPCAP1, AC097520.2, AC097520.1, LNCPRESS2, AC112695.1, GRID2, MTND1P19, AC095059.2, AC095059.1, AC020699.1, AC110800.1.
- chr4:142,023,160–147,544,954, 83 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr4:167,306,910–168,537,786, 10 genes, copy number 8 (within-gene range 6–8): AC079349.1, RN7SL776P, PHBP14, RN7SKP188, AC105148.1, AC116634.1, ANXA10, AC068989.1, DDX60, DDX60L.
- chr5:17,403,889–52,282,859, 428 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr5:162,761,833–165,171,643, 19 genes, copy number 12 (within-gene range 6–12): ARL2BPP5, MRPL57P6, AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC010291.1, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P.
- chr6:89,560,875–90,587,072, 20 genes, copy number 10 (within-gene range 6–10): AL159174.1, LYRM2, MDN1, AL096678.1, DNAJC19P6, PIMREGP3, CASP8AP2, Y_RNA, RPL22P14, AL353692.1, GJA10, Y_RNA, BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7.
- chr6:107,152,562–109,483,219, 60 genes, copy number 7 (within-gene range 5–7): PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4, SEC63, RNU6-437P, RPL23AP50, AL024507.2, AL024507.1, SNORA73, MTHFD2P3, RPL3P7, Z98200.1, OSTM1, Y_RNA, OSTM1-AS1, NR2E1, AL078596.1, SNX3, Z98742.2, RNA5SP212, Z98742.4, Z98742.1, RNU6-1144P, AFG1L, Z98742.3, AL356121.2, AL356121.1, AL353706.1, RNU6-770P, AL139106.1, AL391646.1, FOXO3, SUMO2P8, LINC00222, ZNF259P1, Z95118.2, Z95118.1, ARMC2, AL445189.1, ATP5MFP2, ARMC2-AS1, SESN1, AL390208.1, RNU6-653P, CEP57L1, CCDC162P, AL359711.1, PTCHD3P3, RNY3P11, RPL7P28, CD164, AL359711.2, PPIL6, SMPD2, MICAL1, ZBTB24.
- chr6:116,571,409–116,829,083, 6 genes, copy number 8: RWDD1, RSPH4A, ZUP1, KPNA5, FAM162B, GPRC6A.
- chr6:118,934,770–120,015,257, 10 genes, copy number 8 (within-gene range 5–8): AL137009.1, FAM184A, Y_RNA, MIR548B, AL022722.2, MAN1A1, AL022722.1, RNU6-194P, AL078600.1, MIR3144.
- chr6:122,211,648–159,917,447, 599 genes, copy number 7–8 (broad region; genes not listed).
- chr6:162,568,379–169,425,156, 121 genes, copy number 7 (broad region; genes not listed).
- chr7:2,906,142–19,146,253, 233 genes, copy number 7–13 (broad region; genes not listed).
- chr7:22,118,236–24,694,193, 52 genes, copy number 7–9: RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1, TOMM7, AC005682.2, SNHG26, SNORD93, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7, AC003087.1, RNA5SP228, AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14, AC005084.1.
- chr7:25,593,304–35,254,100, 202 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:63,291,518–71,713,600, 212 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:80,742,538–96,709,891, 186 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:100,875,103–105,522,271, 121 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:128,207,872–143,546,735, 440 genes, copy number 7–30 (broad region; genes not listed).
- chr10:8,400,860–8,724,288, 6 genes, copy number 7: AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1.
- chr11:7,222,933–8,178,903, 34 genes, copy number 7: AC027804.1, MIR302E, SYT9, AC107884.1, OLFML1, PPFIBP2, AC107884.2, CYB5R2, OVCH2, AC104237.2, AC104237.3, AC044810.3, AC104237.1, OR10AB1P, OR5P4P, AC044810.2, OR5P1P, AC044810.1, OR5P2, OR5P3, OR5E1P, RNU6-943P, OR10A6, OR10A3, NLRP10, EIF3F, COX6CP5, CASC23, TUB, AC116456.1, TUB-AS1, AC116456.2, RIC3, RIC3-DT.
- chr11:13,826,843–15,930,951, 28 genes, copy number 8 (within-gene range 3–8): AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682.
- chr11:101,029,624–102,903,953, 41 genes, copy number 24–39: PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P.
- chr12:32,985,838–34,058,745, 13 genes, copy number 7: ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P, AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2.
- chr12:40,393,395–41,774,671, 12 genes, copy number 7: MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400.
- chr14:22,086,407–22,505,167, 62 genes, copy number 9 (broad region; genes not listed).
- chr15:29,609,676–33,310,659, 116 genes, copy number 7 (broad region; genes not listed).
- chr15:58,410,569–61,635,449, 79 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr19:94,062–24,163,425, 1,295 genes, copy number 7–10 (broad region; genes not listed).
- chr19:28,883,430–31,466,431, 48 genes, copy number 8 (within-gene range 6–8): LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1.
- chr19:38,647,649–39,111,493, 27 genes, copy number 9: ACTN4, AC008649.2, CAPN12, AC022144.1, LGALS7, LGALS7B, RNU6-140P, LGALS4, ECH1, AC008982.1, AC104534.1, HNRNPL, AC008982.2, RINL, AC011455.1, SIRT2, NFKBIB, CCER2, SARS2, AC011455.2, MRPS12, ERVK9-11, FBXO17, AC011455.8, FBXO27, AC010605.1, ACP7.
- chr19:40,230,317–40,740,860, 25 genes, copy number 9 (within-gene range 5–9): AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4, SHKBP1, LTBP4, NUMBL, COQ8B, RNU6-195P, ITPKC.
- chr19:41,833,686–48,025,154, 310 genes, copy number 7–8 (broad region; genes not listed).
- chr19:52,511,282–53,270,932, 39 genes, copy number 8 (within-gene range 6–8): AC022150.3, ZNF808, ZNF701, RPL39P34, AC022150.1, ZNF137P, ZNF83, AC022150.2, AC022150.4, ZNF611, ZNF600, ZNF28, PABPN1P2, ZNF468, ZNF320, AC010487.2, ZNF888, AC010487.1, ZNF321P, ZNF816-ZNF321P, ZNF816, AC010328.3, ZNF702P, AC010328.2, AC010328.1, ERVV-1, ERVV-2, ZNF160, ZNF415, ZNF347, ZNF665, AC092070.1, AC092070.2, NDUFV2P1, ZNF677, AC092070.3, VN1R2, VN1R4, AC092070.4.
- chr20:1,023,874–21,970,783, 395 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr20:30,309,015–64,313,132, 895 genes, copy number 7–15 (broad region; genes not listed).
- chr21:10,328,411–16,645,467, 90 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr21:23,352,929–33,310,187, 201 genes, copy number 13–22 (within-gene range 3–22) (broad region; genes not listed).
- chr22:35,066,136–40,410,289, 211 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
